Somatic mutation profile of tumor specimen MMRF_1210_1_BM_CD138pos (aliquot MMRF_1210_1_BM_CD138pos_T2_KHS5U_L16531) from MMRF case MMRF_1210, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.2 years (24,550 days).
Specimen MMRF_1210_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d87f1134-bc70-4060-824e-81c6656df5c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1210_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1210_1_PB_Whole_C1_KHS5U_L16530; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c8a0666-d525-4ecd-9954-4e1d90380321

The open-access MAF lists 109 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 25, Intron 18, Silent 11, 5'UTR 7, RNA 5, Frame Shift Del 3, 5'Flank 3, Splice Region 2, Splice Site 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs373490478; called by muse, mutect2, varscan2
- AFF1 | c.3065C>G p.T1022S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1195725970; called by muse, mutect2, varscan2
- C1orf198 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377026998, COSV64174942; called by muse, mutect2, varscan2
- CEP162 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57619656; called by muse, mutect2, varscan2
- CRMP1 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs910781348, COSV61482769; called by muse, mutect2, varscan2
- IGHJ5 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 20/24 reads (83%) | PolyPhen benign (0.003); catalogued as rs782494105; called by muse, varscan2
- IGHV1-69 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs567659422; called by muse, mutect2, varscan2
- LRRC66 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs534526166; called by muse, mutect2, varscan2
- OPN4 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV99618284; called by muse, mutect2, varscan2
- RASA2 | c.2275_2276del p.E759Kfs*12 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as rs756946687; called by mutect2, pindel, varscan2
- RGL3 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760059667; called by muse, mutect2, varscan2
- SEMA6A | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772134310; called by muse, mutect2
- SPOCK3 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV62726899; called by muse, mutect2, varscan2
- STAT3 | c.1366-5C>T | Splice Region (SNP) | VAF 32/52 reads (62%) | catalogued as rs951615323; called by muse, mutect2, varscan2
- STYXL2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768021668, COSV54810267; called by muse, mutect2, varscan2
- SYNPO | c.1256C>T p.T419M (on ENST00000394243 / NM_001166208.2; = p.T175M on NM_007286.6) | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs777440231; called by muse, mutect2, varscan2
- UBR5 | c.8187+1G>A p.X2729_splice | Splice Site (SNP) | VAF 5/75 reads (7%) | catalogued as COSV55282267; called by muse, mutect2
- ZNF257 | c.757A>G p.R253G | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71306613; called by muse, varscan2
- ADGRL2 | c.2338-8T>C | Splice Region (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- ATP2B2 | c.1840A>G p.K614E (on ENST00000352432; = p.K580E on NM_001683.5) | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC61 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CIT | c.5515C>G p.L1839V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAJB8 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 139/142 reads (98%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP14 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- EIF4G1 | c.630+1G>A p.X210_splice (on ENST00000346169 / NM_198241.3; = p.X14_splice on NM_004953.5) | Splice Site (SNP) | VAF 84/167 reads (50%) | called by muse, mutect2, varscan2
- FAT4 | c.2333T>C p.I778T | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.172); called by muse, mutect2
- IL18R1 | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2
- KLF4 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL45 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO9A | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PABPN1 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PATJ | c.647T>A p.I216N | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PAX1 | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); called by muse, mutect2
- PPRC1 | c.1891_1897del p.L631Tfs*36 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- RAB3A | c.143C>G p.T48R | Missense Mutation (SNP) | VAF 210/440 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RASA2 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- TENT5C | c.153_177del p.I51Mfs*13 | Frame Shift Del (DEL) | VAF 10/128 reads (8%) | called by mutect2, pindel
- TXNDC5 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB16 | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- H3C3 | c.123C>T p.R41= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as rs372565854; called by muse, mutect2, varscan2
- IGHJ6 | c.51C>T p.T17= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs372706912; called by muse, varscan2
- LMNB2 | c.498C>T p.A166= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- MLXIPL | c.1020G>C p.V340= | Silent (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- PHC3 | c.2394G>A p.L798= (on ENST00000494943 / NM_001308116.2; = p.L810= on NM_024947.4) | Silent (SNP) | VAF 32/238 reads (13%) | catalogued as COSV71948442; called by muse, mutect2, varscan2
- QRFPR | c.846T>C p.F282= | Silent (SNP) | VAF 120/583 reads (21%) | called by muse, mutect2, varscan2
- RNASEH2A | c.726G>A p.Q242= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- SLC19A1 | c.871C>T p.L291= | Silent (SNP) | VAF 142/448 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.15330C>T p.F5110= (on ENST00000591111; = p.F4183= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/194 reads (30%) | called by muse, mutect2, varscan2
- ZNF26 | c.747G>A p.Q249= | Silent (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- ZNF317 | c.372G>A p.Q124= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- AC012236.1 | n.170C>G | RNA (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- C9orf57 | c.*302C>A | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- CHPF2 | c.-686T>C | 5'UTR (SNP) | VAF 49/179 reads (27%) | catalogued as rs190803273; called by muse, mutect2, varscan2
- COL4A1 | c.553-17T>C | Intron (SNP) | VAF 24/53 reads (45%) | catalogued as rs1439737234; called by muse, varscan2
- EP400 | c.*387A>G | 3'UTR (SNP) | VAF 9/41 reads (22%) | catalogued as rs1031934661, COSV57784755; called by muse, mutect2, varscan2
- ETS1 | c.*391T>G | 3'UTR (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- FZD8 | c.*1025C>G | 3'UTR (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- GPR78 | c.-158G>A | 5'UTR (SNP) | VAF 54/103 reads (52%) | called by muse, mutect2, varscan2
- GRHL3 | c.17+32T>C | Intron (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- GRM5 | c.662-61818T>G | Intron (SNP) | VAF 86/227 reads (38%) | called by muse, mutect2, varscan2
- GSTM4 | c.567+338A>C | Intron (SNP) | VAF 75/76 reads (99%) | called by muse, mutect2, varscan2
- GYPA | c.136+116A>C | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99301327; called by muse, mutect2, varscan2
- H4C9 | c.*56C>T | 3'UTR (SNP) | VAF 80/176 reads (45%) | catalogued as COSV62889813; called by muse, mutect2, varscan2
- IFIT1B | c.*458C>A | 3'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-34T>A | 5'UTR (SNP) | VAF 30/78 reads (38%) | catalogued as rs567710056; called by muse, varscan2
- IGLL5 | c.-47G>C | 5'UTR (SNP) | VAF 24/63 reads (38%) | catalogued as rs567223608, COSV101597139; called by muse, mutect2, varscan2
- IL17RD | c.*4164G>T | 3'UTR (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- KIF25 | c.93-28A>G | Intron (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.*71C>A | 3'UTR (SNP) | VAF 100/373 reads (27%) | catalogued as rs1228635274; called by muse, mutect2, varscan2
- LAMC2 | c.*76G>A | 3'UTR (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- LINC01159 | n.229T>A | RNA (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- LMBRD2 | c.*5610A>T | 3'UTR (SNP) | VAF 18/63 reads (29%) | called by mutect2, varscan2
- MAP2K1 | c.1068+91C>T | Intron (SNP) | VAF 107/211 reads (51%) | called by muse, mutect2, varscan2
- MIR5007 | n.2G>C | RNA (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- MMP27 | c.-11G>T | 5'UTR (SNP) | VAF 33/342 reads (10%) | called by muse, mutect2
- MTX3 | c.*1934T>G | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- MYOCD | chr17:12665924 C>A | 5'Flank (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- NDST1 | c.*3176C>G | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- NELFA | c.668-137C>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- NMI | c.340+61G>A | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2
- OR10AB1P | n.1361T>C | RNA (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- PDCL | c.*1127C>T | 3'UTR (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- PHLDA1 | c.-732_-731insT | 5'UTR (INS) | VAF 32/76 reads (42%) | called by mutect2, pindel*, varscan2
- PIP5K1C | c.1920+1572C>T | Intron (SNP) | VAF 18/104 reads (17%) | catalogued as rs572656496; called by muse, mutect2, varscan2
- POU2F3 | c.-58G>A | 5'UTR (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- PREX2 | c.*3890T>G | 3'UTR (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- QDPR | c.629+476C>G | Intron (SNP) | VAF 61/180 reads (34%) | catalogued as rs1031603658; called by muse, mutect2, varscan2
- RN7SL860P | chr19:22602317 T>C | 3'Flank (SNP) | VAF 44/333 reads (13%) | called by muse, mutect2, varscan2
- SERF2 | chr15:43791998 A>T | 5'Flank (SNP) | VAF 34/472 reads (7%) | called by muse, mutect2
- SIPA1L3 | c.2030-63G>A | Intron (SNP) | VAF 22/223 reads (10%) | catalogued as rs764851309; called by muse, mutect2, varscan2
- SKP1 | c.*542T>A | 3'UTR (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- SLC24A5 | c.301+881A>G | Intron (SNP) | VAF 34/195 reads (17%) | called by muse, mutect2, varscan2
- SMPD4 | c.*453C>A | 3'UTR (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- SNX33 | c.*3636G>A | 3'UTR (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- SRSF6 | c.*751A>C | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- SSU72 | c.224+1775C>T | Intron (SNP) | VAF 40/150 reads (27%) | catalogued as rs759680033; called by muse, mutect2, varscan2
- SYBU | chr8:109645388 A>G | 5'Flank (SNP) | VAF 66/137 reads (48%) | called by muse, mutect2, varscan2
- TLN2 | c.5736+266G>T | Intron (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- TMEM185B | c.*5del | 3'UTR (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- TRMO | c.410-442G>A | Intron (SNP) | VAF 18/224 reads (8%) | catalogued as rs770686239, COSV100796018; called by muse, mutect2
- TRMT44 | c.*113C>T | 3'UTR (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- TRPM3 | c.1154+8103T>C | Intron (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.2410-28G>A | Intron (SNP) | VAF 19/31 reads (61%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*186_*208del | 3'UTR (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- VNN1 | c.*511G>A | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- ZNF516 | c.*3985C>T | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- ZNF525 | c.*621A>G | 3'UTR (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- ZNF720 | c.*49G>C | 3'UTR (SNP) | VAF 167/370 reads (45%) | called by muse, mutect2
- ZNF725P | n.180C>T | RNA (SNP) | VAF 64/369 reads (17%) | called by muse, mutect2, varscan2
